Somatic mutation profile of tumor specimen TCGA-63-A5MR-01A (aliquot TCGA-63-A5MR-01A-31D-A27K-08) from TCGA case TCGA-63-A5MR, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB.
Specimen TCGA-63-A5MR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 570a6798-ab92-4014-93a6-82c50d6406be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-A5MR-10A (Blood Derived Normal), aliquot TCGA-63-A5MR-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dbe9db4-606b-42f0-91fa-7380bedf41d2

The open-access MAF lists 188 somatic variants for this specimen: 141 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 44, Nonsense Mutation 18, Splice Site 4, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXL2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 9/94 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM082718, COSV57725966, COSV57728681; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 22/56 reads (39%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 31/65 reads (48%) | catalogued as rs878853944, COSV64306603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2756T>G p.M919R | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.514); catalogued as COSV99712966; called by muse, mutect2, varscan2
- AC004593.2 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs895621580, COSV56092827; called by muse, mutect2, varscan2
- AC023055.1 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100278525; called by muse, mutect2
- ACACB | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.023); catalogued as rs746703562, COSV100622844; called by muse, mutect2, varscan2
- ACRBP | c.1539G>T p.E513D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99976100; called by muse, mutect2, varscan2
- ADAL | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101052529; called by muse, mutect2, varscan2
- ADD2 | c.2108C>G p.S703* | Nonsense Mutation (SNP) | VAF 28/356 reads (8%) | catalogued as COSV100035564; called by muse, mutect2
- ADGRL3 | c.1197C>A p.D399E (on ENST00000506720 / NM_001322402.2; = p.D331E on NM_015236.6) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.14); catalogued as rs1393595833, COSV101547095; called by muse, mutect2, varscan2
- ADGRV1 | c.4157A>T p.K1386I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101315886; called by muse, mutect2, varscan2
- AHNAK | c.2601G>T p.E867D | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs556148558, COSV57237157; called by muse, mutect2, varscan2
- ALG8 | c.469A>T p.I157F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100220074; called by muse, varscan2
- ANKMY2 | c.540G>C p.M180I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100187081; called by muse, mutect2, varscan2
- ANKRD30A | c.4015C>G p.H1339D (on ENST00000611781; = p.H1283D on NM_052997.2) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100653476, COSV64615610; called by muse, mutect2, varscan2
- APC2 | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99279405; called by muse, mutect2
- ARHGEF10 | c.83G>A p.R28Q (on ENST00000398564; = p.R4Q on NM_014629.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.019); catalogued as rs777269503, COSV100034465; called by muse, mutect2, varscan2
- BAZ2A | c.3976A>G p.I1326V | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99466057; called by muse, mutect2, varscan2
- BMP10 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV54895260; called by muse, mutect2, varscan2
- BRWD3 | c.5396G>A p.G1799E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100956005; called by muse, mutect2, varscan2
- CALCR | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV100810525; called by muse, mutect2, varscan2
- CBLL2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100081584; called by muse, mutect2, varscan2
- CCDC83 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV99721676; called by muse, mutect2
- CELF3 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99310271; called by muse, mutect2, varscan2
- CEP72 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs1287651749, COSV99374404; called by muse, mutect2
- CNGA2 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100323648, COSV61705312; called by muse, mutect2
- COL11A1 | c.596A>T p.D199V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100616426; called by muse, mutect2, varscan2
- COL6A5 | c.6511C>A p.P2171T (on ENST00000312481; = p.P2167T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.058); catalogued as COSV55213985; called by muse, mutect2, varscan2
- CYRIB | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV101310015, COSV67830645; called by muse, mutect2, varscan2
- DENND3 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs751024080, COSV99370902; called by muse, mutect2, varscan2
- DEPDC1 | c.1155A>T p.L385F | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100920303; called by muse, mutect2, varscan2
- DMD | c.5279T>C p.L1760P | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100819575; called by muse, mutect2, varscan2
- DOCK11 | c.4877C>T p.A1626V | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV52248809; called by muse, mutect2
- DSG1 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99935994; called by muse, mutect2, varscan2
- DYNC1H1 | c.9490C>T p.R3164* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100794846; called by muse, mutect2, varscan2
- ELP2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100626826; called by muse, mutect2, varscan2
- EML4 | c.998A>C p.D333A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100580873; called by muse, mutect2, varscan2
- ERCC2 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101228885, COSV67268042; called by muse, mutect2, varscan2
- ERICH3 | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58614310; called by muse, mutect2
- ESF1 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99176349; called by muse, mutect2, varscan2
- EVI5 | c.1387C>G p.L463V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV100945255; called by muse, mutect2
- FAM163A | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as COSV100523019; called by muse, mutect2, varscan2
- FBXL13 | c.17T>C p.M6T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100501569; called by muse, mutect2, varscan2
- FDCSP | c.115T>A p.S39T | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.423); catalogued as COSV100525762; called by muse, mutect2, varscan2
- FLACC1 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV53783685, COSV99630208; called by muse, mutect2, varscan2
- FLNB | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99913061; called by muse, mutect2, varscan2
- G6PD | c.794T>A p.L265Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100854942, COSV100855023; called by muse, mutect2, varscan2
- GHRH | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765871814, COSV99411141; called by muse, mutect2, varscan2
- GPR15 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV99423740; called by muse, mutect2
- HERPUD2 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100257938; called by muse, mutect2, varscan2
- HOXD10 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV50891786; called by muse, mutect2, varscan2
- IL7R | c.1210C>A p.L404I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as rs761882064, COSV100286263, COSV57407104; called by muse, mutect2, varscan2
- INSIG1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.103); catalogued as COSV60919643, COSV60921239; called by muse, mutect2, varscan2
- JHY | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs746470145, COSV99913176; called by muse, mutect2, varscan2
- KCNG4 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV100377053; called by muse, mutect2, varscan2
- KCNK9 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100270955; called by muse, mutect2, varscan2
- KMT2D | c.6926C>G p.S2309* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV56421807, COSV99981350; called by muse, mutect2, varscan2
- LILRB1 | c.1424G>T p.G475V (on ENST00000427581; = p.G438V on NM_006669.6) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV100207266; called by muse, mutect2, varscan2
- LMTK3 | c.4313C>T p.P1438L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs1304748307, COSV99540463; called by muse, mutect2
- LUM | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99899014; called by muse, mutect2, varscan2
- MED12 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100377881; called by muse, mutect2
- MIA2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1262052832, COSV99697637; called by muse, mutect2, varscan2
- MORC1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV99226105; called by muse, mutect2, varscan2
- MRGPRX3 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV101283531; called by muse, mutect2, varscan2
- MRPL13 | c.307-1G>A p.X103_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100085431; called by muse, mutect2
- MSN | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV100814204; called by muse, mutect2, varscan2
- MSTO1 | c.1283+2T>G p.X428_splice | Splice Site (SNP) | VAF 16/105 reads (15%) | catalogued as rs768834113, COSV99824214; called by muse, mutect2, varscan2
- MUC20 | c.1626T>G p.S542R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as COSV100291145; called by muse, mutect2, varscan2
- MYO7B | c.5309G>T p.R1770L | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101268145; called by muse, mutect2, varscan2
- MYO9A | c.6833C>G p.S2278* | Nonsense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100613433; called by muse, mutect2
- NEDD4 | c.798A>T p.L266F | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100163697; called by muse, mutect2, varscan2
- NLGN3 | c.1978C>A p.R660S (on ENST00000358741 / NM_181303.2; = p.R640S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV100704745, COSV62443031; called by muse, mutect2, varscan2
- NLRP14 | c.1456T>A p.F486I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100204937; called by muse, mutect2, varscan2
- NOS1 | c.2796C>G p.F932L | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500053, COSV100500554; called by muse, mutect2, varscan2
- NOTCH1 | c.1256-1G>A p.X419_splice | Splice Site (SNP) | VAF 21/50 reads (42%) | catalogued as COSV99487713; called by muse, mutect2, varscan2
- NPL | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.872); catalogued as COSV99277525; called by muse, mutect2, varscan2
- NPL | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV99277530; called by muse, mutect2, varscan2
- OAZ1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1483978338, COSV100457299; called by muse, mutect2, varscan2
- OLFML2B | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 106/380 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV99668412; called by muse, mutect2, varscan2
- OR10AG1 | c.877A>T p.R293* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100400075, COSV56634479; called by muse, mutect2, varscan2
- OR4K2 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100064449; called by muse, mutect2, varscan2
- OR6K3 | c.812C>T p.S271L (on ENST00000368146; = p.S255L on NM_001005327.2) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.403); catalogued as rs79482939, COSV63745622, COSV63746585; called by muse, mutect2, varscan2
- OSR1 | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99693676; called by muse, mutect2, varscan2
- PAH | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100188020; called by muse, mutect2, varscan2
- PCDHA10 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100250259, COSV56486470; called by muse, mutect2, varscan2
- PCDHA8 | c.1301C>A p.S434* | Nonsense Mutation (SNP) | VAF 58/231 reads (25%) | catalogued as COSV100970716, COSV65336294; called by muse, mutect2, varscan2
- PFKFB1 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | PolyPhen probably damaging (0.999); catalogued as rs368958510, COSV66629156; called by muse, mutect2, varscan2
- PLAG1 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100387895; called by muse, mutect2, varscan2
- PLCXD3 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as rs749287158, COSV60606708; called by muse, mutect2, varscan2
- PLSCR5 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs780470028, COSV101494487; called by muse, mutect2, varscan2
- POGLUT2 | c.743C>G p.S248* | Nonsense Mutation (SNP) | VAF 99/353 reads (28%) | catalogued as COSV101050788, COSV65683114; called by muse, mutect2, varscan2
- PPP1R10 | c.2632C>T p.H878Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV64740315; called by muse, mutect2, varscan2
- PPT1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100858382, COSV65655973; called by muse, mutect2, varscan2
- RB1CC1 | c.2941C>T p.Q981* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV99212239; called by muse, mutect2, varscan2
- RECQL4 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs750245958, COSV99467533; called by muse, mutect2, varscan2
- RTL9 | c.1852C>G p.L618V | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); catalogued as COSV101511677; called by muse, mutect2, varscan2
- RTP5 | c.527G>A p.W176* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as rs778687546, COSV100574722; called by muse, varscan2
- RXRG | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as COSV100717526; called by muse, mutect2, varscan2
- RYR2 | c.8257G>T p.V2753F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100770003; called by muse, mutect2, varscan2
- SAGE1 | c.1595C>A p.T532N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.664); catalogued as COSV100187182; called by muse, mutect2, varscan2
- SEMA5B | c.2110G>T p.V704L | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV52110662, COSV99531700; called by muse, mutect2, varscan2
- SLAMF6 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100924883; called by muse, mutect2, varscan2
- SLC25A24 | c.442A>G p.R148G | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99916209; called by muse, mutect2, varscan2
- SLC35F3 | c.425A>T p.D142V (on ENST00000366617 / NM_001300845.1; = p.D211V on NM_173508.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100784781; called by muse, mutect2
- SMPD2 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1301480148, COSV99237965; called by muse, mutect2, varscan2
- SMPDL3B | c.605C>G p.A202G | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV100875310, COSV65870707; called by muse, mutect2, varscan2
- SNRNP40 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as rs1417346929, COSV99745297; called by muse, mutect2, varscan2
- SNX18 | c.1442A>G p.D481G | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100410434; called by muse, mutect2, varscan2
- SPATA31D1 | c.2887T>A p.S963T | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.653); catalogued as COSV100782761; called by muse, mutect2, varscan2
- SPSB4 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 5/86 reads (6%) | catalogued as COSV60149579; called by muse, mutect2
- STON1 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100561818; called by muse, mutect2
- SV2C | c.14A>G p.Y5C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100456110; called by muse, mutect2, varscan2
- SYTL5 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV99937216; called by muse, mutect2, varscan2
- TBCCD1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as rs140309382; called by muse, mutect2, varscan2
- TECTB | c.408G>A p.Q136= | Splice Region (SNP) | VAF 8/103 reads (8%) | catalogued as COSV101027694; called by muse, mutect2
- TGM6 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV99171777; called by muse, mutect2, varscan2
- TGM6 | c.862T>A p.L288M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171778; called by muse, mutect2, varscan2
- TNKS | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100126933; called by muse, mutect2, varscan2
- TP53 | c.102del p.L35Cfs*9 | Frame Shift Del (DEL) | VAF 108/317 reads (34%) | catalogued as COSV52833841; called by mutect2, pindel, varscan2
- TRAF6 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV100777688; called by muse, mutect2, varscan2
- TRIM63 | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as rs1025169410, COSV100958151; called by muse, mutect2, varscan2
- TRMT12 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV100149178; called by muse, mutect2, varscan2
- TXNDC16 | c.606-2A>G p.X202_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99909184; called by muse, mutect2, varscan2
- USH2A | c.5879C>A p.P1960H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100234215; called by muse, varscan2
- USP53 | c.3101C>T p.S1034L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99917712; called by muse, mutect2, varscan2
- WDR64 | c.3045C>A p.Y1015* | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100843768; called by muse, mutect2, varscan2
- XDH | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.91); catalogued as COSV101052195; called by muse, mutect2, varscan2
- XPNPEP2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV64368811; called by muse, mutect2, varscan2
- ZFAT | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100914554; called by muse, mutect2, varscan2
- ZFHX3 | c.5422C>T p.Q1808* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV99200003; called by muse, mutect2
- ZNF222 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs141160266, COSV99496341; called by muse, mutect2, varscan2
- ZNF335 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs1159669364, COSV100532958; called by muse, mutect2, varscan2
- ZNF416 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99543813; called by muse, mutect2, varscan2
- ZNF439 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.046); catalogued as COSV100397470, COSV58309510; called by muse, mutect2, varscan2
- ZNF646 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV100336651; called by muse, mutect2, varscan2
- CNOT1 | c.557_589del p.S186_G197delins* | Nonsense Mutation (DEL) | VAF 105/461 reads (23%) | called by mutect2, pindel
- HLA-B | c.824_825insA p.G276Wfs*13 | Frame Shift Ins (INS) | VAF 14/63 reads (22%) | called by mutect2, pindel*, varscan2
- MUC2 | c.401A>T p.Y134F | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated, low confidence (0.7); called by muse, mutect2, varscan2
- TECPR2 | c.2414del p.G805Afs*95 | Frame Shift Del (DEL) | VAF 54/281 reads (19%) | called by mutect2, pindel, varscan2
- TUT1 | c.1690_1693del p.Q564Tfs*71 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.2895G>C p.R965= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV61262128; called by muse, mutect2, varscan2
- CACNA1E | c.1398C>T p.R466= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100702472; called by muse, mutect2, varscan2
- CELF3 | c.624C>A p.T208= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99310274; called by muse, mutect2, varscan2
- CHD7 | c.4572C>T p.S1524= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs984598194, COSV101418239; called by muse, mutect2, varscan2
- CPE | c.600G>A p.V200= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs368903815; called by muse, mutect2, varscan2
- DDX60L | c.2721C>T p.L907= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs763769948, COSV99487582; called by muse, mutect2, varscan2
- DHX36 | c.690T>G p.G230= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100273574; called by muse, mutect2, varscan2
- DNAJC14 | c.531C>G p.L177= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV57914456; called by muse, mutect2
- ERAP1 | c.1626A>G p.V542= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99700914; called by muse, mutect2
- FASN | c.4227G>A p.Q1409= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs1420506507, COSV100147751; called by muse, mutect2, varscan2
- GOLGB1 | c.6654G>A p.A2218= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as rs1163280233, COSV100510809; called by muse, mutect2
- GP2 | c.1209C>T p.A403= (on ENST00000381362 / NM_001007240.3; = p.A400= on NM_001502.4) | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV100221471; called by muse, mutect2, varscan2
- HYDIN | c.5665C>T p.L1889= | Silent (SNP) | VAF 9/63 reads (14%) | called by mutect2, varscan2
- IGLON5 | c.726G>T p.A242= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV99570683; called by muse, mutect2, varscan2
- KCNA4 | c.537G>T p.V179= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100068925; called by muse, mutect2, varscan2
- KNG1 | c.1917C>T p.L639= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as COSV99405512; called by muse, mutect2
- KRBA1 | c.660G>C p.V220= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs773722180, COSV99752626; called by muse, mutect2, varscan2
- LAMA1 | c.1800A>T p.V600= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV101056292; called by muse, mutect2, varscan2
- LMNA | c.1923G>T p.L641= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100738657; called by muse, mutect2, varscan2
- LRFN1 | c.177G>T p.V59= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99952924; called by muse, varscan2
- LRRC37A | c.3681G>A p.A1227= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs1195162507, COSV100208168; called by muse, mutect2, varscan2
- MEGF10 | c.2502C>T p.I834= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99174929; called by muse, mutect2, varscan2
- MYO15A | c.1569C>T p.S523= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1369481157, COSV99232616; called by muse, mutect2, varscan2
- MYPN | c.3585G>A p.V1195= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as COSV100589931; called by muse, mutect2, varscan2
- NCAPG | c.660G>C p.V220= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV99265940; called by muse, mutect2, varscan2
- NKRF | c.61C>T p.L21= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs749369156, COSV100441648; called by muse, mutect2, varscan2
- OR14C36 | c.786G>A p.A262= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as rs143199703, COSV58601678; called by muse, mutect2, varscan2
- OR9A2 | c.729T>C p.C243= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100628211; called by muse, mutect2, varscan2
- PCDH17 | c.3126G>T p.A1042= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100931621, COSV100931767, COSV64975173; called by muse, mutect2, varscan2
- PPIF | c.381C>T p.D127= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs201670150; called by muse, mutect2, varscan2
- RTL5 | c.405G>A p.A135= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1347258964, COSV65452879; called by muse, mutect2
- SLC2A13 | c.450C>T p.A150= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV99786436; called by muse, mutect2, varscan2
- SUPT5H | c.1863C>T p.F621= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs748543064, COSV100782070; called by muse, mutect2, varscan2
- TCF20 | c.5580C>G p.L1860= | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as rs1254203912, COSV100166536; called by muse, mutect2, varscan2
- THNSL2 | c.1110G>T p.S370= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100147467; called by muse, mutect2, varscan2
- TNFAIP2 | c.870C>T p.I290= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs1253513704, COSV60696459; called by muse, mutect2, varscan2
- TOMM40 | c.432A>G p.T144= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs374622148; called by muse, mutect2, varscan2
- TRIM5 | c.1362C>T p.I454= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100000314; called by muse, mutect2, varscan2
- TRMT6 | c.951C>T p.D317= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV52544889; called by muse, mutect2, varscan2
- TXLNG | c.477C>T p.L159= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs1472402261, COSV101200575; called by muse, mutect2, varscan2
- USH2A | c.5880C>T p.P1960= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100234207; called by muse, varscan2
- ZNF184 | c.1944A>G p.E648= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs1317103394, COSV99279637; called by muse, mutect2, varscan2
- ZNF418 | c.63C>G p.L21= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as COSV101268927; called by muse, mutect2, varscan2
- ZPLD1 | c.987C>T p.P329= (on ENST00000466937 / NM_001329788.1; = p.P345= on NM_175056.2) | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV60356318; called by muse, mutect2, varscan2
- MIR526A1 | n.52G>C | RNA (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- SNORD115-16 | n.67G>T | RNA (SNP) | VAF 100/419 reads (24%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438989 G>C | 5'Flank (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
